Somatic mutation profile of tumor specimen C3L-02411-02 (aliquot CPT0111880009) from CPTAC case C3L-02411, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 81.9 years (29,915 days).
Specimen C3L-02411-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a27601c-23b4-48e0-8124-cd8728f7bfde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02411-31 (Blood Derived Normal), aliquot CPT0112840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a765a35d-4117-470a-bfa4-244a80022e12

The open-access MAF lists 1,766 somatic variants for this specimen: 1,157 protein-altering or splice-affecting, 387 silent, 222 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 779, Silent 387, Frame Shift Del 225, Intron 124, Frame Shift Ins 57, Nonsense Mutation 48, 3'UTR 35, Splice Site 28, RNA 23, 5'UTR 21, Splice Region 16, 5'Flank 16.

Variants (750 of 1,766; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNB2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 99/1171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746480833; ClinVar: likely pathogenic; called by muse, mutect2
- CYBB | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 74/640 reads (12%) | catalogued as rs137854588, CM910097, COSV66086104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 85/347 reads (24%) | catalogued as rs754818927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAAF4 | c.583del p.I195* | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | catalogued as rs753649614, CD138279; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 73/267 reads (27%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/413 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRT14 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 255/760 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs57358989, CM950719; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 86/225 reads (38%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 81/297 reads (27%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 63/510 reads (12%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 33/136 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4070C>T p.A1357V (on ENST00000333535 / NM_198056.3; = p.A1356V on NM_000335.5) | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370588133, CM139917; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TBC1D4 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199560195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 48/494 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- A2M | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.05); catalogued as rs766640574; called by muse, mutect2, varscan2
- ABCA9 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756210320, COSV60620151; called by muse, mutect2, varscan2
- ABCG4 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs1312211427; called by muse, mutect2, varscan2
- ACACB | c.4289C>T p.A1430V | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs887481398; called by muse, mutect2, varscan2
- ACER2 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 106/270 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs768162227; called by muse, mutect2, varscan2
- ACKR3 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1559473742, COSV56023116; called by muse, mutect2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, mutect2, varscan2
- ADAM11 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs370821656; called by muse, mutect2, varscan2
- ADAMTS14 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 37/410 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs770333353; called by muse, mutect2
- ADAMTS14 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs538290907, COSV64605067; called by muse, mutect2, varscan2
- ADAMTS16 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 208/545 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.265); catalogued as COSV56986510; called by mutect2, varscan2
- ADAMTSL4 | c.963del p.T322Lfs*21 | Frame Shift Del (DEL) | VAF 55/307 reads (18%) | catalogued as rs748115277, COSV55000781; called by mutect2, pindel, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRD2 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1464681818, COSV100601368; called by muse, mutect2, varscan2
- ADGRF5 | c.1854del p.K618Nfs*40 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as COSV51932176; called by mutect2, pindel, varscan2
- ADRA1A | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52374678; called by muse, mutect2, varscan2
- ADRA2A | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs886590597; called by muse, mutect2, varscan2
- AEBP2 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV56863837; called by muse, mutect2, varscan2
- AGAP5 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 108/1162 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs907695812; called by muse, mutect2, varscan2
- AHNAK2 | c.3770C>G p.P1257R | Missense Mutation (SNP) | VAF 207/642 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60914772; called by muse, mutect2, varscan2
- AIM2 | c.1018A>C p.K340Q | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as COSV63698777; called by muse, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 82/224 reads (37%) | catalogued as rs748776119, COSV59276444; called by mutect2, varscan2
- AL645922.1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs779595202; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 20/145 reads (14%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALX3 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100873878; called by muse, mutect2, varscan2
- AMBN | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs141401324; called by muse, mutect2
- AMPD2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs753173769, COSV99857862; called by muse, mutect2, varscan2
- ANAPC1 | c.3767G>A p.G1256D | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs927539848, COSV100594684; called by mutect2, varscan2
- ANAPC1 | c.1716T>G p.N572K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs1175944249; called by muse, mutect2, varscan2
- ANKRD26 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65775370; called by muse, mutect2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | catalogued as rs1279723268; called by mutect2, varscan2
- ANKRD55 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as rs764843105, COSV61949763; called by muse, mutect2, varscan2
- ANO3 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99880783; called by muse, mutect2
- ANTXRL | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs1226859344; called by muse, mutect2, varscan2
- APOBR | c.1049-2A>G p.X350_splice (on ENST00000431282; = p.S358= on NM_018690.4) | Splice Site (SNP) | VAF 5/14 reads (36%) | catalogued as rs770373316; called by muse, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 20/210 reads (10%) | catalogued as COSV57429840; called by mutect2, pindel
- ARHGEF10 | c.3502C>T p.L1168F (on ENST00000398564; = p.L1143F on NM_014629.4) | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs770414770; called by muse, mutect2
- ARHGEF25 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs1464651792; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 36/228 reads (16%) | catalogued as rs758608743; called by mutect2, varscan2
- ARMC5 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as rs1306044293; called by muse, varscan2
- ARMC5 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs777214700; called by muse, mutect2, varscan2
- ARVCF | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1271913721; called by muse, mutect2, varscan2
- ASCL3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs1251816665; called by muse, mutect2
- ASH1L | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs548853139, COSV64206807; called by muse, mutect2, varscan2
- ASPG | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs756621157, COSV71933559; called by muse, mutect2, varscan2
- ATF7IP | c.1093_1095del p.P365del | In Frame Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs757972204; called by pindel, varscan2
- ATG2A | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as rs1281116232; called by muse, mutect2
- ATN1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as rs1555143919, COSV100755976; called by muse, mutect2, varscan2
- ATP10D | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 187/597 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs201342683; called by muse, mutect2, varscan2
- ATP2C1 | c.75del p.A26Qfs*21 | Frame Shift Del (DEL) | VAF 38/304 reads (13%) | catalogued as rs1559936852, COSV60757077; called by mutect2, pindel, varscan2
- AURKB | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs766373871; called by muse, mutect2
- B4GALNT4 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as rs1224094553, COSV57324599, COSV57325779; called by muse, mutect2, varscan2
- BASP1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.772); catalogued as rs751498324, COSV100493932; called by muse, mutect2, varscan2
- BAZ1B | c.4262G>A p.R1421H | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs139742468; called by muse, mutect2
- BCL9L | c.1640A>G p.Q547R | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs200078960; called by muse, mutect2, varscan2
- BCORL1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as rs140430106; called by muse, mutect2, varscan2
- BMP1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60479869; called by muse, mutect2, varscan2
- BOC | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368545065, COSV56358829; called by muse, mutect2, varscan2
- BTD | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM993554; called by muse, mutect2, varscan2
- C10orf105 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936905416; called by muse, mutect2
- C14orf180 | c.135del p.S46Pfs*3 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs761345073; called by mutect2, varscan2
- C16orf54 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774872519, COSV61477003; called by muse, mutect2, varscan2
- C19orf18 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs35437132; called by muse, mutect2, varscan2
- CABIN1 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs773238327, COSV54077056; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 52/317 reads (16%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMSAP3 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs760521201; called by muse, mutect2, varscan2
- CAPN3 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 73/571 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58826230; called by muse, mutect2, varscan2
- CAPN3 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 193/540 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as rs201566716; ClinVar: uncertain significance; called by muse, varscan2
- CASD1 | c.52A>G p.S18G | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV51970522; called by muse, varscan2
- CASK | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1012863843, COSV59369981; called by muse, mutect2
- CCBE1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 140/580 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1174131304; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC30 | c.1642C>T p.H548Y (on ENST00000340612; = p.H505Y on NM_001080850.3) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs1172923662; called by muse, mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 77/330 reads (23%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCDC88B | c.2935C>T p.R979W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1249028192, COSV57268582; called by muse, mutect2, varscan2
- CCKBR | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224436970, COSV58099220; called by muse, mutect2, varscan2
- CCNE1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs141578348; called by muse, mutect2
- CCNF | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs527471283, COSV99564097; called by muse, mutect2, varscan2
- CCNH | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs140747495, COSV56926609; called by muse, mutect2, varscan2
- CCP110 | c.1529G>A p.S510N | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.07); catalogued as COSV66817370; called by muse, mutect2, varscan2
- CD177 | c.1258del p.V420Wfs*30 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | catalogued as COSV65121341; called by mutect2, varscan2
- CD84 | c.965C>T p.A322V (on ENST00000311224 / NM_001184879.2; = p.A305V on NM_003874.4) | Missense Mutation (SNP) | VAF 83/568 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV60871170; called by muse, mutect2, varscan2
- CD84 | c.389-1G>T p.X130_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as rs1328390115, COSV100245914; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 35/347 reads (10%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC37 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 69/339 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55770179; called by muse, mutect2, varscan2
- CDCA7 | c.274C>T p.R92C (on ENST00000347703 / NM_145810.3; = p.R171C on NM_031942.5) | Missense Mutation (SNP) | VAF 62/638 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs780814022; called by muse, mutect2
- CDH22 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 120/375 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779818992; called by muse, mutect2, varscan2
- CDH24 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52981947; called by muse, mutect2, varscan2
- CDH8 | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 17/425 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54904948; called by muse, mutect2
- CDH9 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346865409, COSV50303173, COSV50488057; called by muse, mutect2, varscan2
- CDH9 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1457198445; called by muse, mutect2, varscan2
- CDKN2A | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 114/734 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58715027; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | catalogued as rs747064410; called by mutect2, varscan2
- CHAC2 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV54858669; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 32/195 reads (16%) | catalogued as rs1322050057; called by mutect2, varscan2
- CHST11 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as COSV57984798; called by muse, mutect2
- CIB2 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV51947759, COSV51948745; called by muse, mutect2
- CLK1 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as rs763052500; called by muse, mutect2, varscan2
- CLSPN | c.2892G>T p.Q964H | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV99230378; called by muse, mutect2, varscan2
- CLU | c.187dup p.T63Nfs*25 | Frame Shift Ins (INS) | VAF 148/537 reads (28%) | catalogued as rs747368775; called by mutect2, pindel, varscan2
- CLUH | c.1568G>A p.R523H (on ENST00000435359; = p.R561H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs554152603; called by muse, mutect2, varscan2
- CNTLN | c.4175del p.K1392Rfs*3 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs747411468; called by mutect2, pindel, varscan2
- CNTNAP1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 127/567 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV52847776, COSV52850324; called by muse, mutect2, varscan2
- CNTNAP5 | c.2687G>A p.S896N | Missense Mutation (SNP) | VAF 54/444 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs776065308; called by muse, mutect2, varscan2
- COIL | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs181585875; called by muse, mutect2
- COL22A1 | c.1622del p.P541Lfs*9 | Frame Shift Del (DEL) | VAF 91/292 reads (31%) | catalogued as rs1563754947, COSV57325891; called by mutect2, varscan2
- COP1 | c.1613-2A>G p.X538_splice | Splice Site (SNP) | VAF 44/314 reads (14%) | catalogued as COSV58167115; called by muse, mutect2, varscan2
- CORO7 | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768577818, COSV52031178; called by muse, mutect2, varscan2
- CPXM2 | c.1101C>T p.V367= | Splice Region (SNP) | VAF 18/153 reads (12%) | catalogued as rs139790511; called by muse, mutect2, varscan2
- CRAMP1 | c.3410G>A p.S1137N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51966698; called by muse, varscan2
- CSNK1G1 | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100274388; called by muse, mutect2, varscan2
- CTAG2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs782359239, COSV55996248; called by muse, mutect2, varscan2
- CTNNAL1 | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1349960988; called by muse, mutect2, varscan2
- CUL9 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs760368335; called by muse, mutect2, varscan2
- DAPK3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 211/624 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.408); catalogued as rs763032380; called by muse, mutect2, varscan2
- DARS2 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 116/520 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217906974, COSV99508627; called by muse, mutect2, varscan2
- DCAF12L1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 91/474 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs1321889996; called by muse, mutect2, varscan2
- DEAF1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs762639219, COSV58605983; ClinVar: uncertain significance; called by muse, mutect2
- DENND1C | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1425871660; called by muse, mutect2, varscan2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 35/137 reads (26%) | catalogued as rs1208100549; called by mutect2, pindel, varscan2
- DIRAS1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs770364194; called by muse, mutect2, varscan2
- DLG3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1188616963; called by muse, mutect2
- DNAH1 | c.3260G>A p.R1087H | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs145381093, COSV70236309; called by muse, mutect2, varscan2
- DNAH7 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 24/318 reads (8%) | catalogued as rs768660117, COSV56781409; called by muse, mutect2
- DNAJB6 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs368565876; called by muse, mutect2, varscan2
- DOCK4 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 19/359 reads (5%) | catalogued as rs1375815588, COSV70319710; called by muse, mutect2
- DOCK5 | c.1735del p.M579Wfs*8 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs1282784562; called by mutect2, pindel, varscan2
- DPF1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV62792518; called by muse, mutect2, varscan2
- DPP6 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.346); catalogued as rs1417889961; called by muse, mutect2, varscan2
- DPP9 | c.1918G>A p.V640I (on ENST00000598800; = p.V669I on NM_139159.5) | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs772138491; called by muse, mutect2
- DRD5 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 31/353 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs745947661, COSV58576784; called by muse, mutect2
- DRP2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.043); catalogued as rs1489322241; called by muse, mutect2, varscan2
- DSG2 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 53/149 reads (36%) | catalogued as CM148579; called by muse, mutect2, varscan2
- DYRK1B | c.1267del p.L423Wfs*80 | Frame Shift Del (DEL) | VAF 35/99 reads (35%) | catalogued as COSV59914053; called by mutect2, pindel, varscan2
- EBF1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1234645991, COSV58196565; called by muse, mutect2, varscan2
- EEFSEC | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 66/497 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs775321881; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 146/394 reads (37%) | catalogued as rs746692720; called by mutect2, varscan2
- EMILIN3 | c.2091G>T p.E697D | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1241360691; called by muse, mutect2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as rs761717176; called by mutect2, varscan2
- EP400 | c.8352G>A p.M2784I | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.777); catalogued as rs762858368; called by muse, mutect2, varscan2
- EPPK1 | c.5750G>A p.S1917N | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as rs868913138, COSV73260927; called by muse, mutect2, varscan2
- EPRS1 | c.943+1G>A p.X315_splice | Splice Site (SNP) | VAF 36/80 reads (45%) | catalogued as rs774022716, COSV65100239; called by muse, mutect2
- EPS8L2 | c.1681-4G>A | Splice Region (SNP) | VAF 8/33 reads (24%) | catalogued as rs1249716662, COSV59348005; called by muse, mutect2, varscan2
- ERCC6L2 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs532544338; called by muse, mutect2, varscan2
- ERGIC3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 83/378 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs757775545; called by muse, mutect2, varscan2
- ERO1A | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1472131472; called by muse, mutect2, varscan2
- ESRP1 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 111/330 reads (34%) | catalogued as COSV64408863; called by muse, mutect2, varscan2
- EYA1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376931849, COSV58162404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F10 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 50/435 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs778616029, COSV65020746; called by muse, mutect2, varscan2
- F13B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 91/381 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- FAAP100 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1259932099, COSV100585405; called by muse, mutect2, varscan2
- FABP9 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as rs749835352, COSV66911575; called by muse, mutect2, varscan2
- FAM102A | c.776G>A p.R259H (on ENST00000373095 / NM_001035254.3; = p.R117H on NM_203305.2) | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200021618; called by muse, mutect2, varscan2
- FAM149B1 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs375530140; called by muse, mutect2, varscan2
- FAM155B | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs1364475803; called by mutect2, varscan2
- FAM160A2 | c.2656C>T p.R886* (on ENST00000449352 / NM_001098794.2; = p.R900* on NM_032127.4) | Nonsense Mutation (SNP) | VAF 52/165 reads (32%) | catalogued as rs1215619539; called by muse, mutect2, varscan2
- FAM205A | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778196529, COSV66490141; called by muse, mutect2
- FAM47A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs201264239, COSV60497671; called by muse, mutect2, varscan2
- FAM53A | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs779306779; called by muse, mutect2, varscan2
- FANCE | c.544del p.Q182Rfs*114 | Frame Shift Del (DEL) | VAF 99/297 reads (33%) | catalogued as rs1561789651, COSV100003664; called by mutect2, pindel, varscan2
- FAR2 | c.1329del p.K443Nfs*4 | Frame Shift Del (DEL) | VAF 58/304 reads (19%) | catalogued as COSV99479542; called by mutect2, pindel, varscan2
- FARS2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs745400923, COSV51165800; called by muse, mutect2, varscan2
- FAT1 | c.6080G>A p.R2027H | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs745765579, COSV71674714; called by muse, mutect2, varscan2
- FAT2 | c.6908G>A p.R2303Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs200235163; called by muse, mutect2, varscan2
- FAT4 | c.3505C>T p.R1169W | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs190175933; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FGG | c.1289del p.G430Efs*33 (on ENST00000336098 / NM_021870.3; = p.G430Efs*24 on NM_000509.5) | Frame Shift Del (DEL) | VAF 150/305 reads (49%) | catalogued as rs1560833290, COSV60195824; called by mutect2, pindel, varscan2
- FLG2 | c.7108del p.S2370Afs*32 | Frame Shift Del (DEL) | VAF 91/331 reads (27%) | catalogued as rs1457697914; called by mutect2, pindel, varscan2
- FLNA | c.6007C>T p.R2003C (on ENST00000369850 / NM_001110556.2; = p.R1995C on NM_001456.3) | Missense Mutation (SNP) | VAF 204/610 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV61050925; called by muse, mutect2, varscan2
- FLNC | c.5408G>A p.R1803Q | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs757482925; ClinVar: uncertain significance; called by muse, mutect2
- FOS | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 158/490 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1260142158; called by muse, mutect2, varscan2
- FOSL2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs377464718; called by muse, mutect2, varscan2
- FOXC1 | c.821del p.P274Rfs*41 | Frame Shift Del (DEL) | VAF 125/431 reads (29%) | catalogued as CX117371; called by mutect2, pindel, varscan2
- FOXC2 | c.112A>G p.M38V | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1346828342; called by muse, mutect2, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 71/328 reads (22%) | catalogued as COSV56761013; called by mutect2, varscan2
- FOXI1 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1235637800; called by muse, mutect2
- FOXK1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100196063; called by muse, mutect2, varscan2
- FOXN4 | c.1155del p.H385Qfs*21 | Frame Shift Del (DEL) | VAF 52/251 reads (21%) | catalogued as COSV54499136; called by mutect2, pindel, varscan2
- FRAS1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 43/519 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs886059627; ClinVar: uncertain significance; called by muse, mutect2
- FSIP2 | c.5210T>A p.I1737N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1351679732, COSV100555542; called by muse, mutect2
- FTH1 | c.446T>C p.L149S | Missense Mutation (SNP) | VAF 102/658 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99861287; called by muse, varscan2
- FUBP1 | c.1345-5del | Splice Region (DEL) | VAF 20/156 reads (13%) | catalogued as rs545766306; called by mutect2, varscan2
- FUT1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 196/558 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs750207214, COSV59567592; called by muse, mutect2, varscan2
- FZR1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs567376375; called by muse, mutect2, varscan2
- GAD2 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 53/198 reads (27%) | catalogued as rs897876627, COSV52150849; called by muse, mutect2, varscan2
- GAL3ST1 | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 113/484 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1249100828; called by mutect2, varscan2
- GATA3 | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV60516225; called by muse, mutect2
- GBP1 | c.1172dup p.R392Afs*3 | Frame Shift Ins (INS) | VAF 120/377 reads (32%) | catalogued as rs777277713; called by mutect2, varscan2
- GDF1 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated, low confidence (0.28); catalogued as rs772809060, COSV99439130; called by muse, mutect2, varscan2
- GET3 | c.1002C>A p.F334L | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV50379387; called by muse, mutect2
- GFRA1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 176/476 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456628506; called by muse, mutect2, varscan2
- GHITM | c.220dup p.I74Nfs*3 | Frame Shift Ins (INS) | VAF 13/107 reads (12%) | catalogued as rs745461487; called by mutect2, pindel
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as rs750227570; called by mutect2, varscan2
- GJA5 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 189/1001 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54784727; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 18/147 reads (12%) | catalogued as rs752075537; called by mutect2, varscan2
- GNPTAB | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54778801; called by muse, mutect2
- GOLGA6L9 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 235/853 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as rs1314005946; called by muse, mutect2, varscan2
- GPR158 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs1197032663; called by muse, mutect2
- GPT | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 108/487 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs1032661716, COSV99477311; called by muse, mutect2, varscan2
- GRIK3 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs753008196, COSV66136278; called by muse, mutect2
- GRM1 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV51121869; called by muse, mutect2, varscan2
- GSK3A | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 119/501 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV55899917; called by muse, mutect2, varscan2
- GXYLT2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs75794282; called by muse, mutect2, varscan2
- HAGHL | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 38/652 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as rs776632526; called by muse, mutect2
- HCN4 | c.3371del p.G1124Vfs*57 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | catalogued as rs1255143771; called by mutect2, pindel, varscan2
- HDAC10 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 97/367 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs779615440, COSV50585923; called by muse, mutect2, varscan2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 85/263 reads (32%) | catalogued as rs747537946; called by mutect2, varscan2
- HECTD3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.096); catalogued as COSV55800945; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HID1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as rs375659521; called by muse, mutect2, varscan2
- HIF1A | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs372868999; called by muse, mutect2, varscan2
- HMGCS1 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 29/85 reads (34%) | catalogued as COSV57291163; called by muse, mutect2, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs779589617; called by mutect2, varscan2
- HNRNPC | c.425G>A p.R142H (on ENST00000420743; = p.R129H on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1164890552, COSV60147108; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs767148651; called by mutect2, varscan2
- HOOK3 | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.636); catalogued as COSV56879283; called by muse, mutect2, varscan2
- HOXA3 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1286530524, COSV57829041; called by muse, mutect2
- HOXD3 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1389150341; called by muse, mutect2, varscan2
- HS3ST2 | c.949dup p.T317Nfs*22 | Frame Shift Ins (INS) | VAF 98/446 reads (22%) | catalogued as rs1329578843; called by mutect2, varscan2
- HTR1E | c.801dup p.F268Lfs*4 | Frame Shift Ins (INS) | VAF 70/310 reads (23%) | catalogued as rs753568078; called by mutect2, varscan2
- HTR2B | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs181580625, COSV51450018; called by muse, varscan2
- HTR5A | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs147688293, COSV55282547; called by muse, mutect2
- HTR6 | c.1226dup p.L410Afs*67 | Frame Shift Ins (INS) | VAF 96/508 reads (19%) | catalogued as rs752215098; called by mutect2, pindel, varscan2
- IARS2 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV56963181; called by muse, mutect2, varscan2
- ICAM3 | c.75A>G p.P25= | Splice Region (SNP) | VAF 16/242 reads (7%) | catalogued as rs909005220; called by muse, mutect2
- IER5L | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs1173240152; called by muse, mutect2, varscan2
- IFI16 | c.1174del p.T392Qfs*11 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | catalogued as COSV55533843, COSV99857104; called by mutect2, pindel
- IFI27L2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779353746, COSV99032030; called by muse, mutect2, varscan2
- IGDCC4 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1457672409, COSV100732779; called by muse, mutect2
- IGF2R | c.5053G>A p.D1685N | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs747421150, COSV63628763; called by muse, mutect2, varscan2
- IL6R | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs867606554; called by muse, varscan2
- ILK | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 105/499 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs745314579; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS5 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 101/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746468648; called by muse, mutect2, varscan2
- IPO4 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs958410864, COSV100268923; called by muse, mutect2, varscan2
- IQGAP2 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs760813383, COSV57171597; called by mutect2, varscan2
- IRAG1 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746132888; called by muse, mutect2
- IRF2BP1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 126/347 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs1435786635; called by muse, mutect2, varscan2
- IRGQ | c.114del p.E39Rfs*11 | Frame Shift Del (DEL) | VAF 79/255 reads (31%) | catalogued as COSV60671635; called by mutect2, pindel, varscan2
- ISYNA1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1483817264; called by muse, mutect2, varscan2
- ITGAX | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs559233176, COSV51649221; called by muse, mutect2
- ITIH5 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 48/740 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1467593204, COSV53664001, COSV53668973; called by muse, mutect2
- ITM2B | c.93dup p.D32Rfs*12 | Frame Shift Ins (INS) | VAF 64/299 reads (21%) | catalogued as rs746700992; called by mutect2, varscan2
- ITM2C | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763337530, COSV58398608; called by muse, mutect2
- ITPR1 | c.2927T>C p.I976T (on ENST00000354582; = p.I961T on NM_002222.7) | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1012491864; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 11/105 reads (10%) | catalogued as rs755650243; called by mutect2, varscan2
- JARID2 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs762009475; called by muse, mutect2, varscan2
- JMJD4 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 103/468 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV59919378; called by muse, mutect2, varscan2
- KAT6B | c.4121G>A p.G1374E | Missense Mutation (SNP) | VAF 81/646 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV54743294, COSV54745814; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 98/212 reads (46%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC2 | c.47del p.G16Afs*32 | Frame Shift Del (DEL) | VAF 168/855 reads (20%) | catalogued as COSV54368827; called by mutect2, pindel, varscan2
- KCNC3 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 264/685 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65388101; called by muse, mutect2, varscan2
- KCTD18 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs372353449; called by muse, mutect2, varscan2
- KCTD9 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55341462, COSV99648783; called by muse, mutect2, varscan2
- KDM6B | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs751046746; called by mutect2, varscan2
- KIAA0319 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs141114963; called by muse, mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs746314511; called by mutect2, varscan2
- KIF13A | c.3345dup p.V1116Sfs*4 | Frame Shift Ins (INS) | VAF 39/120 reads (33%) | catalogued as rs1346755993; called by mutect2, varscan2
- KIF7 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1315005502; called by muse, mutect2
- KLF16 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 151/722 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759591358, COSV51736606; called by muse, mutect2, varscan2
- KLHL26 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 82/378 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.953); catalogued as rs769972361, COSV56318585; called by muse, mutect2, varscan2
- KMT2A | c.6581G>A p.R2194H | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs370899148; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 44/290 reads (15%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRT15 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as rs757934023; called by muse, mutect2, varscan2
- LDB3 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 89/443 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs727505129, COSV53939322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LENG8 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58725914; called by muse, mutect2, varscan2
- LHCGR | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs559262616, COSV54293731, COSV99683806; called by muse, mutect2
- LIG4 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 176/512 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748301113, COSV63596416; called by muse, mutect2
- LILRA5 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV56642482; called by muse, mutect2, varscan2
- LIPG | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 36/565 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs777932618; called by muse, mutect2
- LPA | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 194/1095 reads (18%) | catalogued as rs1191914217; called by muse, varscan2
- LRCH2 | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781879974; called by muse, varscan2
- LRP1 | c.4736A>G p.Y1579C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV54523826; called by muse, mutect2, varscan2
- LRRC40 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 45/108 reads (42%) | catalogued as rs767301282; called by muse, varscan2
- LRRC4C | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs767793951, COSV53432956, COSV53438666; called by muse, mutect2, varscan2
- LRRIQ1 | c.3634C>T p.R1212* | Nonsense Mutation (SNP) | VAF 128/336 reads (38%) | catalogued as rs200693636, COSV101280637, COSV67827773; called by mutect2, varscan2
- LSP1 | c.322del p.Q108Sfs*31 | Frame Shift Del (DEL) | VAF 44/102 reads (43%) | catalogued as rs752018434; called by mutect2, pindel, varscan2
- LVRN | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs1174455864; called by muse, mutect2, varscan2
- MACF1 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 51/190 reads (27%) | catalogued as COSV100487282; called by muse, mutect2, varscan2
- MAMSTR | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs751815874; called by muse, mutect2, varscan2
- MASP2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376909147; called by muse, mutect2, varscan2
- MATN4 | c.1298G>A p.R433H (on ENST00000372754; = p.R392H on NM_003833.4) | Missense Mutation (SNP) | VAF 58/241 reads (24%) | PolyPhen probably damaging (0.995); catalogued as rs1016514539, COSV61352450; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MDC1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64522983; called by muse, mutect2, varscan2
- MED12 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV100377960; called by muse, mutect2, varscan2
- MED26 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs368197948; called by muse, mutect2, varscan2
- MEN1 | c.670-5del | Splice Region (DEL) | VAF 56/324 reads (17%) | catalogued as rs772016629; ClinVar: benign / likely benign; called by mutect2, pindel, varscan2
- MEOX2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320459432, COSV56288190; called by muse, varscan2
- MFAP5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753275305, COSV63945356; called by muse, mutect2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs769987847; called by mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MISP | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.111); catalogued as rs772278393; called by muse, mutect2, varscan2
- MMP15 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs927682751; called by muse, mutect2, varscan2
- MOGS | c.1759del p.R587Gfs*7 | Frame Shift Del (DEL) | VAF 23/235 reads (10%) | catalogued as COSV51968753; called by mutect2, pindel, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL21 | c.449+8C>T | Splice Region (SNP) | VAF 24/188 reads (13%) | catalogued as rs58968627; called by muse, mutect2, varscan2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs758439223; called by mutect2, pindel, varscan2
- MRPL42 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV62355789; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 87/289 reads (30%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MS4A6A | c.553_554del p.T185Sfs*29 | Frame Shift Del (DEL) | VAF 38/276 reads (14%) | catalogued as COSV60616210; called by mutect2, pindel, varscan2
- MSLN | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 148/422 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs761467681, COSV53505368; called by muse, mutect2, varscan2
- MTCL1 | c.3460C>T p.R1154W (on ENST00000306329 / NM_001378206.1; = p.R835W on NM_015210.4) | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs370454729; called by muse, mutect2, varscan2
- MTHFR | c.1799A>C p.E600A | Missense Mutation (SNP) | VAF 136/518 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57171350; called by muse, varscan2
- MTMR4 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749303819, COSV60201325; called by muse, mutect2, varscan2
- MUC16 | c.29168C>T p.T9723I | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs566132260; called by muse, mutect2, varscan2
- MYBPC1 | c.1052C>T p.T351I (on ENST00000550270 / NM_206820.2; = p.T376I on NM_002465.4) | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as rs758009052; called by muse, mutect2, varscan2
- MYL9 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs752683922; called by muse, mutect2, varscan2
- MYO1E | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 173/455 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs150735139; called by muse, mutect2, varscan2
- MYO1G | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs777783175; called by muse, mutect2, varscan2
- MYO5A | c.4318del p.I1440Lfs*4 | Frame Shift Del (DEL) | VAF 23/243 reads (9%) | catalogued as rs1567030410; called by mutect2, pindel, varscan2
- NAV1 | c.4733G>A p.R1578H | Missense Mutation (SNP) | VAF 33/620 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs781210039, COSV99819145; called by muse, mutect2
- NBN | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs1554559212, COSV55371530, COSV55376901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBPF10 | c.11049G>T p.K3683N | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.888); catalogued as rs782494127; called by muse, mutect2
- NCAPH | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1233502636; called by muse, mutect2
- NCBP2L | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as rs776948555, COSV64943909; called by muse, mutect2, varscan2
- NCKAP5 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs773014477, COSV104399506; called by muse, mutect2
- NCKIPSD | c.1918A>G p.I640V | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1262626575; called by muse, mutect2, varscan2
- NID1 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 102/498 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as COSV51621476, COSV51630192; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 51/175 reads (29%) | catalogued as rs111948120; called by mutect2, varscan2
- NIPBL | c.1513del p.R505Efs*35 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as rs34314728; called by mutect2, pindel, varscan2
- NLRP13 | c.2647G>C p.A883P | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV61620906; called by muse, mutect2, varscan2
- NOXA1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 75/387 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756331723, COSV58161791; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 87/303 reads (29%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NPFFR1 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 42/431 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs368051663; called by muse, mutect2
- NPS | c.244del p.T82Lfs*10 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs1455620486; called by mutect2, pindel, varscan2
- NR1I2 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 207/589 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs763780333, COSV100561549, COSV61979959; called by muse, mutect2, varscan2
- NUFIP1 | c.494del p.K165Rfs*38 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs770344882; called by mutect2, varscan2
- NUP210L | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 63/229 reads (28%) | catalogued as rs1179865434, COSV55153062; called by muse, mutect2, varscan2
- NXF1 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV53672360; called by muse, mutect2, varscan2
- NXN | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398377070; called by muse, mutect2
- OBSCN | c.17899C>T p.R5967C | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs919675899, COSV52785484; called by muse, mutect2, varscan2
- OBSL1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867139989, COSV99216753; called by muse, mutect2
- OMA1 | c.560A>C p.N187T | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62256025; called by muse, mutect2, varscan2
- OR4P4 | c.315dup p.G106Wfs*14 | Frame Shift Ins (INS) | VAF 16/120 reads (13%) | catalogued as rs748398423; called by mutect2, varscan2
- OR8K3 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as rs779168193; called by muse, mutect2
- OSM | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1333949548; called by muse, mutect2
- OVOL1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs899307004, COSV60120399; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PASD1 | c.2023A>T p.T675S | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV64855629; called by muse, mutect2
- PCDHA11 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 221/662 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.104); catalogued as rs376620715, COSV56521586; called by muse, mutect2, varscan2
- PCDHA4 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV63541380, COSV63542990; called by muse, mutect2, varscan2
- PCDHA8 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 208/672 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs781895761; called by mutect2, varscan2
- PCDHGB4 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 56/643 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763321545, COSV53912675; called by muse, mutect2
- PCDHGC5 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.092); catalogued as rs373526771; called by muse, mutect2, varscan2
- PCSK2 | c.343A>G p.N115D | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs957874782; called by muse, mutect2, varscan2
- PCSK6 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs777544871, COSV59342303; called by muse, mutect2, varscan2
- PCYOX1L | c.910del p.L304Cfs*10 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs1421574639; called by mutect2, pindel
- PDCD6 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1294369854; called by muse, mutect2
- PDE9A | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750539213, COSV99372402; called by muse, mutect2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZRN3 | c.2983A>G p.M995V | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs143168780; called by muse, mutect2, varscan2
- PEAR1 | c.2865del p.R956Gfs*30 | Frame Shift Del (DEL) | VAF 77/291 reads (26%) | catalogued as rs774951036; called by mutect2, pindel, varscan2
- PER1 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs150885062; called by muse, mutect2
- PFAS | c.1410G>T p.Q470H | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV58983776; called by muse, mutect2, varscan2
- PFKP | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462142691, COSV66896578, COSV66899720; called by muse, mutect2, varscan2
- PGBD1 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs756584844; called by muse, mutect2, varscan2
- PGLYRP2 | c.764dup p.R256Sfs*36 | Frame Shift Ins (INS) | VAF 28/269 reads (10%) | catalogued as rs1390617731; called by mutect2, pindel
- PHF12 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs757998998; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | catalogued as rs748850271; called by pindel, varscan2
- PHLDB3 | c.1225del p.R409Dfs*32 | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | catalogued as rs1262981894; called by mutect2, pindel, varscan2
- PI4KA | c.5956G>A p.G1986S | Missense Mutation (SNP) | VAF 52/517 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776288318; called by muse, mutect2, varscan2
- PIEZO1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 221/407 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs768304931, COSV56335930; called by muse, mutect2, varscan2
- PIGS | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371227096; called by muse, mutect2, varscan2
- PIH1D1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 29/377 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV51808448; called by muse, mutect2
- PLD5 | c.218C>T p.A73V (on ENST00000442594; = p.A11V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100138071; called by muse, mutect2, varscan2
- PLEKHA5 | c.2085T>G p.D695E | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.971); catalogued as COSV54712651; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 32/256 reads (13%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLXNA2 | c.4459G>A p.E1487K | Missense Mutation (SNP) | VAF 37/557 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771611862; called by muse, mutect2
- PLXNA3 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1391731317, COSV63755772; called by muse, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- POLR2E | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs376699715; called by muse, varscan2
- POM121L2 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1161354293; called by muse, mutect2, varscan2
- POMGNT1 | c.1943del p.P648Qfs*45 | Frame Shift Del (DEL) | VAF 25/162 reads (15%) | catalogued as rs1557668503; called by mutect2, pindel, varscan2
- POU4F2 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1469974096; called by muse, mutect2, varscan2
- PPP1R12A | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV54109644; called by muse, mutect2
- PREX1 | c.4571C>A p.T1524N | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs374942872; called by muse, mutect2, varscan2
- PRKAG1 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs755677616; called by muse, mutect2, varscan2
- PRPF6 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV53878495; called by muse, mutect2
- PRRT2 | c.640del p.A214Pfs*15 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs769519069; called by pindel, varscan2
- PSME4 | c.3392G>A p.R1131H | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.35); catalogued as rs753202778, COSV66363271; called by muse, mutect2, varscan2
- PTPN21 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.382); catalogued as rs538563931; called by muse, mutect2, varscan2
- RABGAP1 | c.2789dup p.N930Kfs*7 | Frame Shift Ins (INS) | VAF 34/147 reads (23%) | catalogued as rs749213218; called by mutect2, varscan2
- RABL6 | c.1557del p.W520Gfs*79 | Frame Shift Del (DEL) | VAF 41/238 reads (17%) | catalogued as rs755631481, COSV100272944; called by mutect2, pindel, varscan2
- RALGAPA2 | c.3317G>A p.G1106D | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323171507; called by muse, mutect2
- RALGAPB | c.3326G>A p.R1109H | Missense Mutation (SNP) | VAF 107/436 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753525976; called by muse, mutect2, varscan2
- RAPGEF4 | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs368051118; called by muse, mutect2, varscan2
- RARA | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54189681, COSV54192824; called by muse, mutect2, varscan2
- RASL10A | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 107/438 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as rs1047407421; called by muse, mutect2, varscan2
- RDX | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58193448; called by muse, mutect2
- RECQL4 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99467126; called by muse, varscan2
- REEP4 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as rs1370939609; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs759247453; called by mutect2, varscan2
- RGSL1 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772405024, COSV99678357; called by muse, mutect2, varscan2
- RHOT2 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as rs755243388, COSV99554085; called by mutect2, varscan2
- RIMS2 | c.3253C>T p.R1085C (on ENST00000666250 / NM_001348490.2; = p.R893C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs1305079529, COSV51683394; called by muse, mutect2
- RNF213 | c.8876T>C p.L2959P | Missense Mutation (SNP) | VAF 19/594 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100299910; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 215/388 reads (55%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 52/234 reads (22%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RREB1 | c.4338del p.E1447Rfs*81 | Frame Shift Del (DEL) | VAF 62/193 reads (32%) | catalogued as COSV58560368; called by mutect2, pindel, varscan2
- RSPO3 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100759513; called by muse, mutect2, varscan2
- RTL1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs560431230, COSV66017002; called by muse, mutect2, varscan2
- RUFY3 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 43/206 reads (21%) | catalogued as rs201289788; called by muse, mutect2, varscan2
- RYR2 | c.3247del p.E1083Kfs*14 | Frame Shift Del (DEL) | VAF 45/246 reads (18%) | catalogued as COSV63679863; called by mutect2, pindel
- RYR2 | c.6203G>A p.R2068Q | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as rs869025512, COSV63713031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACM1L | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334633812, COSV101203778; called by muse, mutect2, varscan2
- SCAPER | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 23/215 reads (11%) | catalogued as rs1302842375; called by muse, mutect2, varscan2
- SCFD2 | c.152del p.G51Vfs*27 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs753794117; called by mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SDC4 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101023321; called by muse, mutect2, varscan2
- SEC13 | c.450+1G>A p.X150_splice (on ENST00000350697 / NM_183352.3; = p.X153_splice on NM_030673.4) | Splice Site (SNP) | VAF 102/285 reads (36%) | catalogued as rs768669768, COSV61602304; called by muse, mutect2, varscan2
- SEC31A | c.3262C>A p.P1088T (on ENST00000355196 / NM_001318120.1; = p.P1049T on NM_016211.4) | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1801913; called by muse, mutect2, varscan2
- SEMA4D | c.2441G>A p.G814D | Missense Mutation (SNP) | VAF 151/473 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100358580; called by muse, mutect2, varscan2
- SERTM1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59377107; called by muse, mutect2, varscan2
- SGCE | c.1117T>C p.Y373H (on ENST00000647096; = p.Y337H on NM_003919.3) | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs749985422; called by muse, mutect2, varscan2
- SGPP1 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 57/486 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1474081793; called by muse, mutect2, varscan2
- SH3BP4 | c.1007G>T p.S336I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100749361; called by muse, mutect2, varscan2
- SHANK3 | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1221480667; called by muse, mutect2
- SIN3B | c.2183G>C p.S728T | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as rs1172360232; called by muse, mutect2
- SKOR2 | c.1102del p.A368Rfs*128 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | catalogued as rs1341602903; called by mutect2, pindel
- SLC12A6 | c.2029C>T p.R677C (on ENST00000354181 / NM_001365088.1; = p.R626C on NM_005135.2) | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775137770, COSV51624021; called by muse, mutect2, varscan2
- SLC13A4 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757537197; called by muse, mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 31/205 reads (15%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC1A3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs199787096, COSV54314157; called by muse, mutect2, varscan2
- SLC27A6 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 10/121 reads (8%) | catalogued as COSV52483207; called by muse, mutect2
- SLC35B3 | c.249_250del p.I83Mfs*26 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | catalogued as rs1561763394; called by pindel, varscan2
- SLC35G3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 256/764 reads (34%) | catalogued as rs762545351; called by muse, mutect2, varscan2
- SLC6A18 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs767204417; called by muse, mutect2, varscan2
- SLC7A10 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs374673922; called by muse, varscan2
- SLC9A3 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs868752117; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMC5 | c.3199A>G p.T1067A | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1462550347; called by muse, mutect2, varscan2
- SMG9 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs747956190; called by muse, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 9/24 reads (38%) | catalogued as rs746816975; called by mutect2, varscan2
- SMS | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 136/433 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65113958; called by muse, mutect2, varscan2
- SNRNP70 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1326143832; called by muse, mutect2
- SP110 | c.1691del p.P564Lfs*16 | Frame Shift Del (DEL) | VAF 58/241 reads (24%) | catalogued as rs1245290762; called by mutect2, pindel, varscan2
- SP140L | c.1663A>G p.M555V | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1422634459; called by muse, mutect2, varscan2
- SPDL1 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1457520138; called by muse, mutect2
- SPDYC | c.119del p.G40Afs*62 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs1224705180; called by mutect2, pindel, varscan2
- SPG21 | c.487del p.I163* | Frame Shift Del (DEL) | VAF 122/400 reads (31%) | catalogued as rs970163893; called by mutect2, pindel, varscan2
- SPINT1 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59801214; called by muse, mutect2, varscan2
- SPRTN | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1184574595; called by muse, mutect2, varscan2
- SPTBN2 | c.2161C>A p.R721S | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as CM1410223; called by muse, mutect2, varscan2
- SPTBN4 | c.6374C>A p.P2125H | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1456678234, COSV58955589; called by muse, mutect2
- SRC | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62441663; called by muse, mutect2, varscan2
- SRRM1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 101/275 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs756704983; called by muse, mutect2, varscan2
- SSC5D | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs540684155; called by muse, varscan2
- STAB1 | c.3364dup p.R1122Pfs*37 | Frame Shift Ins (INS) | VAF 27/74 reads (36%) | catalogued as rs563085224; called by mutect2, varscan2
- STK10 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as rs375809850; called by muse, mutect2
- STN1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs761593090; called by muse, mutect2, varscan2
- STRADA | c.1084C>T p.R362C (on ENST00000336174 / NM_001363786.1; = p.R325C on NM_153335.6) | Missense Mutation (SNP) | VAF 118/494 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs764311000, COSV51991437; called by muse, varscan2
- STRIP2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV50809994; called by muse, mutect2, varscan2
- SUZ12 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100496810; called by muse, mutect2, varscan2
- SYN2 | c.1403del p.P468Qfs*76 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | catalogued as rs1366030822; called by mutect2, pindel, varscan2
- TACR3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as CM119299, COSV59197428; called by muse, mutect2, varscan2
- TARS3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs1342832303, COSV60108543; called by mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TCP10L2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 113/515 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.034); catalogued as rs577537940; called by muse, mutect2, varscan2
- TECPR2 | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as rs750558246; called by muse, mutect2
- TEX10 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 66/182 reads (36%) | catalogued as rs1270452246; called by muse, varscan2
- TGFBRAP1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 193/552 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs755371712, COSV51513640; called by muse, mutect2, varscan2
- THBS4 | c.85del p.Q29Rfs*13 | Frame Shift Del (DEL) | VAF 18/139 reads (13%) | catalogued as rs771166085; called by mutect2, pindel, varscan2
- THEMIS | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747611832; called by muse, mutect2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV50235787; called by mutect2, pindel
- TINAG | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV52516550; called by muse, mutect2, varscan2
- TLL2 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs374588772, COSV63575357; called by muse, mutect2, varscan2
- TMEM131L | c.1443del p.F481Lfs*21 | Frame Shift Del (DEL) | VAF 48/217 reads (22%) | catalogued as rs1181980974; called by mutect2, pindel, varscan2
- TMEM132C | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1429301838, COSV59419682; called by muse, varscan2
- TMEM143 | c.124del p.R42Gfs*45 | Frame Shift Del (DEL) | VAF 49/271 reads (18%) | catalogued as rs762159291, COSV53158530; called by mutect2, pindel, varscan2
- TMEM191C | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 10/206 reads (5%) | catalogued as rs1444867817; called by muse, mutect2
- TMEM39B | c.590+1G>A p.X197_splice | Splice Site (SNP) | VAF 17/144 reads (12%) | catalogued as rs768718909, COSV60377707; called by muse, mutect2
- TMEM63C | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376516019; called by muse, mutect2, varscan2
- TMPRSS9 | c.1351C>T p.R451C (on ENST00000648592; = p.R417C on NM_182973.2) | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141788773; called by muse, mutect2
- TOX2 | c.1228del p.Q410Sfs*17 (on ENST00000358131 / NM_001098798.2; = p.Q386Sfs*17 on NM_032883.3) | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs758050087; called by mutect2, pindel, varscan2
- TPTE | c.1169A>G p.Q390R (on ENST00000618007 / NM_199261.4; = p.Q372R on NM_199259.4) | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749592520; called by muse, mutect2
- TRIO | c.7425del p.S2476Afs*51 | Frame Shift Del (DEL) | VAF 83/289 reads (29%) | catalogued as rs774597492; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TRO | c.4115G>A p.S1372N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.132); catalogued as COSV51505563; called by muse, mutect2, varscan2
- TSSK2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs750282273, COSV99351055; called by muse, mutect2, varscan2
- TXNRD3 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367586511; called by muse, mutect2, varscan2
- TYR | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as CM041472; called by muse, mutect2, varscan2
- UBR3 | c.4768G>A p.A1590T | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs140078278; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 112/345 reads (32%) | catalogued as rs763652408; called by mutect2, varscan2
- UNC93B1 | c.399dup p.G134Wfs*59 | Frame Shift Ins (INS) | VAF 32/121 reads (26%) | catalogued as rs1490111244; called by mutect2, pindel, varscan2
- UPF1 | c.1475C>T p.T492I (on ENST00000599848 / NM_001297549.2; = p.T481I on NM_002911.4) | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1246297207; called by muse, mutect2
- UPF1 | c.1796C>T p.S599L (on ENST00000599848 / NM_001297549.2; = p.S588L on NM_002911.4) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs762952797; called by muse, mutect2
- USP20 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.767); catalogued as rs1239502791, COSV59613449; called by muse, mutect2, varscan2
- USP40 | c.1808-2A>G p.X603_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as rs1296768080; called by muse, mutect2, varscan2
- UVSSA | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs531138286; called by muse, mutect2, varscan2
- VKORC1L1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 35/203 reads (17%) | catalogued as rs1398969517; called by muse, mutect2, varscan2
- VPS13C | c.10600G>A p.G3534R (on ENST00000644861 / NM_020821.3; = p.G3491R on NM_017684.5) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356765702; called by muse, mutect2, varscan2
- VRTN | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56440957, COSV56444142, COSV99832434; called by muse, mutect2, varscan2
- VWC2L | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV56965792; called by muse, mutect2, varscan2
- WDR1 | c.1585del p.Y529Mfs*26 (on ENST00000382452; = p.Y389Mfs*26 on NM_005112.5) | Frame Shift Del (DEL) | VAF 76/247 reads (31%) | catalogued as rs1451323999, COSV66723865; called by mutect2, pindel, varscan2
- WDR49 | c.745A>T p.I249L (on ENST00000308378 / NM_001366158.1; = p.I590L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1228823711; called by muse, mutect2, varscan2
- WDR81 | c.3269A>G p.Y1090C (on ENST00000409644 / NM_001163809.2; = p.Y39C on NM_152348.4) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1010132159; called by muse, mutect2
- XIRP2 | c.2303G>T p.G768V (on ENST00000628543; = p.G943V on NM_152381.6) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV54682782, COSV54694609; called by muse, mutect2, varscan2
- XKR3 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1209221931, COSV100509340; called by muse, mutect2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 45/153 reads (29%) | catalogued as rs761507279; called by mutect2, pindel, varscan2
- ZBED1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 114/450 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs201125661; called by muse, mutect2, varscan2
- ZBTB16 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 191/615 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60090363; called by muse, mutect2, varscan2
- ZBTB40 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs780952191; called by muse, mutect2
- ZBTB7C | c.960dup p.P321Afs*141 | Frame Shift Ins (INS) | VAF 14/65 reads (22%) | catalogued as rs751294936; called by mutect2, varscan2
- ZC3H12A | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.255); catalogued as rs377089553; called by muse, mutect2, varscan2
- ZC3H12C | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1445578904; called by muse, mutect2, varscan2
- ZDBF2 | c.3886G>A p.V1296I | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs190838042, COSV65628263; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 42/302 reads (14%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFHX2 | c.5770del p.V1924Cfs*6 | Frame Shift Del (DEL) | VAF 34/273 reads (12%) | catalogued as rs748108531; called by pindel, varscan2
- ZFP37 | c.498del p.K166Nfs*19 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | catalogued as COSV100953148; called by mutect2, pindel, varscan2
- ZFP57 | c.529del p.C177Afs*25 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | catalogued as rs1272756745; called by mutect2, pindel, varscan2
- ZFP91 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV60158864; called by muse, mutect2, varscan2
- ZFYVE28 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as rs770346073, COSV52110411; called by muse, mutect2, varscan2
- ZG16B | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 21/431 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1282432606; called by muse, mutect2
- ZGRF1 | c.3638G>A p.R1213Q | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369838525; called by muse, mutect2, varscan2
- ZMIZ2 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs11978942; called by muse, mutect2, varscan2
- ZNF100 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 149/374 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs778689509, COSV59747546; called by muse, mutect2, varscan2
- ZNF317 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 124/389 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs780771548, COSV99927131; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 24/172 reads (14%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF479 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 150/527 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV58642949; called by muse, mutect2, varscan2
- ZNF513 | c.800-2A>G p.X267_splice | Splice Site (SNP) | VAF 163/738 reads (22%) | catalogued as rs1437874151; called by muse, mutect2, varscan2
- ZNF541 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); catalogued as rs1359500511, COSV54546730; called by muse, mutect2
- ZNF598 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 175/552 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1471418297, COSV70910991; called by muse, mutect2, varscan2
- ZNF608 | c.699dup p.H234Afs*34 | Frame Shift Ins (INS) | VAF 49/167 reads (29%) | catalogued as rs780943893; called by mutect2, pindel, varscan2
- ZNF768 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs780989957; called by muse, mutect2, varscan2
- ZNF843 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.447); catalogued as rs1193846048; called by muse, mutect2
- ZNF850 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs778425979; called by muse, mutect2, varscan2
- ZNF865 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.36); catalogued as COSV57596352; called by muse, mutect2, varscan2
- ZSWIM1 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777440000; called by muse, mutect2, varscan2
- ZSWIM8 | c.137_140del p.K46Sfs*27 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as rs1223633594; called by mutect2, pindel, varscan2
- ZSWIM9 | c.1353del p.P452Lfs*18 | Frame Shift Del (DEL) | VAF 46/164 reads (28%) | catalogued as COSV60888067; called by mutect2, pindel, varscan2
- ZZEF1 | c.8359G>A p.E2787K | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as rs1267362816; called by muse, mutect2, varscan2
- ABCA1 | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); called by muse, mutect2
- ABCA10 | c.3927A>C p.K1309N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCC5 | c.757dup p.A253Gfs*8 | Frame Shift Ins (INS) | VAF 185/599 reads (31%) | called by mutect2, pindel, varscan2
- ABCG5 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 155/448 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABHD15 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.195); called by muse, mutect2
- ABL1 | c.1950del p.L651Wfs*43 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- ABTB2 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 107/411 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC013489.1 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ACACB | c.4049G>C p.S1350T | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ACADS | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 76/868 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- ACTL7A | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ACTN2 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 185/811 reads (23%) | called by muse, mutect2, varscan2
- ACTR1A | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADAMTS16 | c.2930G>A p.S977N | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ADAMTS2 | c.2515dup p.D839Gfs*89 | Frame Shift Ins (INS) | VAF 99/469 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.2345del p.T782Sfs*90 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- ADGB | c.3664G>A p.A1222T | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ADGRA2 | c.2957T>C p.L986P | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRB1 | c.2696dup p.Q900Afs*25 | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | called by mutect2, varscan2
- ADGRL1 | c.4208A>G p.E1403G (on ENST00000340736 / NM_001008701.3; = p.E1398G on NM_014921.5) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ADGRV1 | c.453+1G>A p.X151_splice | Splice Site (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- ADH1B | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADNP | c.2531G>T p.W844L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADRA1A | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 153/403 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL1 | c.1433T>C p.M478T | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- AHNAK | c.6857T>C p.V2286A | Missense Mutation (SNP) | VAF 57/676 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2
- AHNAK | c.5077A>G p.K1693E | Missense Mutation (SNP) | VAF 62/544 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- AHRR | c.1055C>A p.P352Q | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- AJM1 | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP5 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- ALPK3 | c.2304del p.K768Nfs*12 | Frame Shift Del (DEL) | VAF 65/281 reads (23%) | called by mutect2, varscan2
- AMER1 | c.519del p.F173Lfs*36 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel
- AMMECR1 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ANKFY1 | c.3384C>G p.H1128Q (on ENST00000341657 / NM_001330063.2; = p.H1129Q on NM_016376.5) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKLE2 | c.2132T>C p.L711P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD17 | c.3901G>A p.G1301S | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKS1B | c.1902del p.G635Dfs*19 | Frame Shift Del (DEL) | VAF 57/174 reads (33%) | called by mutect2, pindel, varscan2
- ANKS4B | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- AP4E1 | c.3380T>C p.L1127P | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- APOB | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 56/451 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- APOBEC3B | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 175/1596 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARF3 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARFGEF3 | c.4066A>G p.M1356V | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- ARHGEF17 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF40 | c.78del p.T27Pfs*19 | Frame Shift Del (DEL) | VAF 95/276 reads (34%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 57/234 reads (24%) | called by mutect2, varscan2
- ARID2 | c.4081A>G p.I1361V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.026); called by muse, mutect2
- ARID3C | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARMC4 | c.1730del p.G577Vfs*9 | Frame Shift Del (DEL) | VAF 28/226 reads (12%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.397del p.A133Lfs*7 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- ARMCX4 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ARV1 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 54/711 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- ASPM | c.5039del p.N1680Mfs*4 | Frame Shift Del (DEL) | VAF 33/224 reads (15%) | called by mutect2, pindel, varscan2
- ATG14 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 88/396 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG2B | c.3301G>T p.G1101C | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP10D | c.1127T>C p.M376T | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ATP2B2 | c.1948A>G p.I650V (on ENST00000352432; = p.I616V on NM_001683.5) | Missense Mutation (SNP) | VAF 139/407 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ATP7A | c.251del p.L84* | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.053); called by muse, mutect2
- ATP8B2 | c.344T>C p.I115T (on ENST00000672630; = p.I82T on NM_001005855.2) | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2
- BCR | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 113/336 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- BHLHA15 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BICD2 | c.1545G>C p.E515D | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BICRAL | c.2989C>A p.P997T | Missense Mutation (SNP) | VAF 24/423 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.784); called by muse, mutect2
- C14orf39 | c.1066A>C p.T356P | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- C18orf54 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- C18orf63 | c.1018del p.M340Cfs*6 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | called by mutect2, varscan2
- C1GALT1C1L | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- C1orf109 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- C2CD2L | c.18del p.Q7Sfs*10 | Frame Shift Del (DEL) | VAF 114/366 reads (31%) | called by mutect2, pindel, varscan2
- C2orf74 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- C7orf57 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1C | c.5391del p.L1798Cfs*54 (on ENST00000399634 / NM_001167625.1; = p.L1798Cfs*42 on NM_000719.7) | Frame Shift Del (DEL) | VAF 16/164 reads (10%) | called by mutect2, pindel
- CACNA1E | c.6115A>G p.M2039V (on ENST00000367573 / NM_001205293.3; = p.M1996V on NM_000721.4) | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- CAPN3 | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 70/692 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- CASK | c.1234-3dup | Splice Region (INS) | VAF 30/169 reads (18%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.3228del p.F1076Lfs*4 | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | called by mutect2, pindel, varscan2
- CAVIN3 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 98/764 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- CCDC157 | c.1122G>A p.V374= | Splice Region (SNP) | VAF 82/226 reads (36%) | called by muse, mutect2, varscan2
- CCDC88C | c.2336G>A p.S779N | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL3L3 | c.192-2A>G p.X64_splice | Splice Site (SNP) | VAF 79/1078 reads (7%) | called by muse, mutect2
- CCN3 | c.569G>T p.R190M | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCP110 | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCRL2 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CD8A | c.509dup p.A171Rfs*12 | Frame Shift Ins (INS) | VAF 25/101 reads (25%) | called by mutect2, pindel, varscan2
- CDC23 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CDC42EP4 | c.696del p.E233Rfs*149 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- CDH23 | c.4178A>G p.D1393G | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- CDH6 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CELSR2 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- CELSR3 | c.9122C>T p.A3041V | Missense Mutation (SNP) | VAF 94/334 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CEMIP | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 56/504 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CENPF | c.6827G>A p.C2276Y | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- CEP170B | c.2822del p.G941Afs*92 (on ENST00000453495; = p.G870Afs*92 on NM_015005.3) | Frame Shift Del (DEL) | VAF 24/216 reads (11%) | called by mutect2, varscan2
- CEP250 | c.4023T>C p.G1341= | Splice Region (SNP) | VAF 32/122 reads (26%) | called by mutect2, varscan2
- CEP350 | c.949A>G p.N317D | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEP350 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.559); called by muse, mutect2
- CHAC1 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 58/330 reads (18%) | called by muse, mutect2, varscan2
- CHD2 | c.3238-1G>A p.X1080_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- CHRNA4 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHST8 | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHSY3 | c.279del p.I95Sfs*83 | Frame Shift Del (DEL) | VAF 134/461 reads (29%) | called by mutect2, pindel, varscan2
- CIITA | c.807del p.S270Vfs*36 | Frame Shift Del (DEL) | VAF 75/300 reads (25%) | called by mutect2, pindel, varscan2
- CLCN5 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.233); called by muse, mutect2
- CLDN14 | c.669del p.S224Qfs*2 | Frame Shift Del (DEL) | VAF 64/203 reads (32%) | called by mutect2, pindel, varscan2
- CMTR2 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
- CNDP2 | c.1331C>G p.A444G | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CNIH2 | c.234_235del p.F78Lfs*36 | Frame Shift Del (DEL) | VAF 74/259 reads (29%) | called by mutect2, pindel, varscan2
- COBL | c.3068del p.P1023Lfs*42 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- COBL | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 86/385 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL11A2 | c.1990G>A p.G664S (on ENST00000341947 / NM_080680.3; = p.G557S on NM_080679.2) | Missense Mutation (SNP) | VAF 163/446 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- COL4A3 | c.3066G>C p.M1022I | Missense Mutation (SNP) | VAF 101/514 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.8244del p.G2749Efs*37 | Frame Shift Del (DEL) | VAF 62/308 reads (20%) | called by mutect2, pindel, varscan2
- COPA | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- COPS5 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CPA6 | c.796del p.R266Vfs*11 | Frame Shift Del (DEL) | VAF 38/316 reads (12%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 78/276 reads (28%) | called by mutect2, varscan2
- CPSF1 | c.2713_2715del p.K905del | In Frame Del (DEL) | VAF 14/116 reads (12%) | called by pindel, varscan2
- CPSF1 | c.2386-2A>G p.X796_splice | Splice Site (SNP) | VAF 75/206 reads (36%) | called by muse, mutect2, varscan2
- CSMD1 | c.1817G>T p.G606V (on ENST00000520002; = p.G605V on NM_033225.6) | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSPG4 | c.6727C>T p.L2243F | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTNNAL1 | c.2195G>A p.S732N | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- CUEDC1 | c.68del p.G23Afs*65 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- CUL3 | c.116del p.N39Mfs*39 | Frame Shift Del (DEL) | VAF 36/338 reads (11%) | called by pindel, varscan2
- CXCR5 | c.721del p.V241* | Frame Shift Del (DEL) | VAF 19/194 reads (10%) | called by mutect2, pindel
- CYFIP1 | c.3314A>G p.D1105G | Missense Mutation (SNP) | VAF 142/393 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CYP19A1 | c.549_550insG p.Y184Vfs*17 | Frame Shift Ins (INS) | VAF 115/331 reads (35%) | called by mutect2, pindel*, varscan2
- CYP3A43 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DAB2IP | c.781G>A p.E261K (on ENST00000408936; = p.E233K on NM_032552.3) | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCLK1 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDAH2 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DENND2B | c.939del p.R315Gfs*18 | Frame Shift Del (DEL) | VAF 43/111 reads (39%) | called by mutect2, pindel, varscan2
- DENND3 | c.2933G>A p.C978Y | Missense Mutation (SNP) | VAF 65/450 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKKL1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DLC1 | c.4532T>C p.I1511T (on ENST00000276297 / NM_001348081.2; = p.I1074T on NM_006094.5) | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DLST | c.812dup p.L271Ffs*5 | Frame Shift Ins (INS) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- DNAJB6 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK1 | c.2780T>C p.L927P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- DOCK1 | c.5402del p.P1801Lfs*14 | Frame Shift Del (DEL) | VAF 114/403 reads (28%) | called by mutect2, pindel, varscan2
- DOCK4 | c.5756G>A p.S1919N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DOCK7 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- DOK5 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.531); called by muse, mutect2
- DOP1B | c.2738A>G p.E913G | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DRP2 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- DVL2 | c.2060del p.P687Hfs*28 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | called by mutect2, pindel, varscan2
- DZIP1 | c.337del p.V113Wfs*6 | Frame Shift Del (DEL) | VAF 67/306 reads (22%) | called by mutect2, varscan2
- EBF2 | c.1379del p.G460Dfs*20 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | called by mutect2, pindel
- EFCAB6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- EFHC1 | c.1221del p.D408Tfs*7 | Frame Shift Del (DEL) | VAF 68/339 reads (20%) | called by mutect2, pindel, varscan2
- EFTUD2 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- EGFL6 | c.118del p.V40Sfs*56 | Frame Shift Del (DEL) | VAF 36/235 reads (15%) | called by mutect2, pindel, varscan2
- EHD1 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 48/602 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- EHHADH | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2A | c.382del p.M128Cfs*86 | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | called by mutect2, pindel, varscan2
- EIF5B | c.315dup p.Q106Tfs*4 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- EMC1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- EMILIN3 | c.889dup p.L297Pfs*24 | Frame Shift Ins (INS) | VAF 76/347 reads (22%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.1027T>A p.C343S | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD6 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EOMES | c.995del p.G332Afs*4 | Frame Shift Del (DEL) | VAF 41/111 reads (37%) | called by mutect2, pindel, varscan2
- EP300 | c.3965C>T p.T1322I | Missense Mutation (SNP) | VAF 60/475 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- EP300 | c.4741T>C p.S1581P | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA10 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPM2AIP1 | c.288_289del p.R96Sfs*21 | Frame Shift Del (DEL) | VAF 104/400 reads (26%) | called by pindel, varscan2
- EQTN | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERFE | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ESCO1 | c.55del p.S19Vfs*17 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel
- EVPL | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- EXOC1 | c.2469del p.G824Vfs*2 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- EXOC8 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 105/549 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- F9 | c.718dup p.W240Lfs*8 | Frame Shift Ins (INS) | VAF 114/523 reads (22%) | called by mutect2, pindel, varscan2
- FA2H | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- FAAH | c.1176-4C>T | Splice Region (SNP) | VAF 30/184 reads (16%) | called by muse, varscan2
- FAM133B | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- FAM135B | c.4014A>G p.T1338= | Splice Region (SNP) | VAF 26/179 reads (15%) | called by muse, mutect2
- FAM53C | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 176/566 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM71E2 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- FASN | c.6547A>G p.T2183A | Missense Mutation (SNP) | VAF 78/636 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- FAT2 | c.11556G>A p.W3852* | Nonsense Mutation (SNP) | VAF 111/343 reads (32%) | called by muse, mutect2, varscan2
- FBF1 | c.1009C>T p.Q337* (on ENST00000586717; = p.Q351* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- FBLN2 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FBXL19 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- FER1L5 | c.2635C>T p.P879S (on ENST00000623019; = p.P884S on NM_001293083.2) | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FGD1 | c.2485C>T p.H829Y | Missense Mutation (SNP) | VAF 176/503 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FLNA | c.6052del p.E2018Sfs*6 (on ENST00000369850 / NM_001110556.2; = p.E2010Sfs*6 on NM_001456.3) | Frame Shift Del (DEL) | VAF 174/609 reads (29%) | called by mutect2, pindel, varscan2
- FLNC | c.8021G>T p.G2674V | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FOXJ3 | c.1352-1G>T p.X451_splice | Splice Site (SNP) | VAF 58/146 reads (40%) | called by muse, mutect2, varscan2
- FRMD4A | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FRRS1 | c.370del p.T124Qfs*20 | Frame Shift Del (DEL) | VAF 55/234 reads (24%) | called by mutect2, pindel, varscan2
- FSIP2 | c.14753T>C p.L4918P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.887); called by muse, mutect2
- FSIP2 | c.17606G>A p.R5869K | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FTCD | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 75/638 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FTH1 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 82/766 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, varscan2
- FUNDC1 | c.20del p.P7Lfs*17 | Frame Shift Del (DEL) | VAF 97/352 reads (28%) | called by mutect2, pindel, varscan2
- FZD8 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABRQ | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GALNT12 | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT8 | c.1052dup p.V352Sfs*13 | Frame Shift Ins (INS) | VAF 80/287 reads (28%) | called by mutect2, pindel, varscan2
- GASK1A | c.1265T>C p.L422P | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
1,016 further variants in this file (407 protein-altering or splice-affecting, 387 silent, 222 other) are not listed here.
